Somatic mutation profile of tumor specimen TCGA-50-5066-01A (aliquot TCGA-50-5066-01A-01D-1625-08) from TCGA case TCGA-50-5066, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.2 years (26,385 days).
Specimen TCGA-50-5066-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b59f8f51-d09c-403b-8ad2-98c9bd65cfb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5066-10A (Blood Derived Normal), aliquot TCGA-50-5066-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3fce5f60-2af0-4b06-bc86-800f42d8e33e

The open-access MAF lists 279 somatic variants for this specimen: 218 protein-altering or splice-affecting, 53 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 192, Silent 53, Nonsense Mutation 14, Frame Shift Del 6, Splice Site 4, Intron 3, RNA 3, 3'UTR 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.755C>A p.A252E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV55950155; called by muse, mutect2, varscan2
- ABCC5 | c.3388G>T p.G1130C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55596926; called by muse, mutect2
- ABCC9 | c.719A>G p.K240R | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV53970002; called by muse, mutect2, varscan2
- ACACB | c.6257G>T p.R2086L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58133536; called by muse, mutect2, varscan2
- ACTRT1 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV64419280; called by muse, mutect2, varscan2
- ADAMTS12 | c.1037C>A p.T346N | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61262000; called by muse, mutect2, varscan2
- ADAMTS17 | c.1975G>C p.G659R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); catalogued as COSV51479234, COSV99170439; called by muse, mutect2
- ADAMTS9 | c.5192A>G p.Y1731C | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.796); catalogued as rs780728947, COSV55780167; called by muse, mutect2, varscan2
- ADH1C | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV72463689; called by muse, mutect2
- AHNAK2 | c.8857G>C p.A2953P | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV60914417; called by muse, mutect2, varscan2
- AKNA | c.175T>G p.F59V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56312398; called by mutect2, varscan2
- ALMS1 | c.2587C>G p.L863V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.138); catalogued as COSV52508786; called by muse, mutect2
- ALPI | c.513G>C p.Q171H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV55014444; called by muse, mutect2, varscan2
- ALPK1 | c.2651G>T p.R884M | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51584570; called by muse, mutect2, varscan2
- AMFR | c.1097G>C p.R366P | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV51921033; called by muse, mutect2
- ANK1 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV55880230; called by muse, mutect2
- ANKEF1 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV101001019, COSV65692358; called by muse, mutect2, varscan2
- ANKS1B | c.1540G>C p.A514P | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100248312, COSV61348985; called by muse, mutect2, varscan2
- ARFGEF1 | c.3766G>T p.V1256F | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51607398; called by muse, mutect2, varscan2
- ARHGAP25 | c.845C>T p.P282L (on ENST00000409202 / NM_001007231.3; = p.P274L on NM_014882.3) | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54901794, COSV54904888; called by muse, mutect2
- ARHGEF12 | c.4157A>G p.E1386G | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV63104299; called by muse, mutect2
- ARPP21 | c.748T>A p.F250I | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.639); catalogued as COSV51796915; called by muse, mutect2
- C14orf39 | c.1697T>C p.I566T | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1305983334, COSV58781539; called by muse, mutect2, varscan2
- C8orf33 | c.458C>G p.P153R | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58895560; called by muse, mutect2, varscan2
- CACNA2D3 | c.1895A>T p.N632I | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55535139; called by muse, mutect2, varscan2
- CALM1 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV63662946; called by muse, mutect2
- CAMTA1 | c.3501G>C p.Q1167H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV57897957; called by muse, mutect2
- CASP5 | c.269A>T p.H90L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV52828346; called by muse, mutect2, varscan2
- CCR4 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100447368; called by muse, mutect2
- CDH12 | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101201360, COSV66395997; called by muse, mutect2
- CDH18 | c.1529G>C p.S510T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV56918965; called by muse, mutect2, varscan2
- CDH9 | c.398G>T p.R133I | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV50276442, COSV50404628; called by muse, mutect2, varscan2
- CDYL | c.1061A>G p.H354R (on ENST00000328908 / NM_001368125.1; = p.H300R on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV59359513; called by muse, mutect2
- CHRNA1 | c.744C>A p.Y248* (on ENST00000261007 / NM_001039523.3; = p.Y223* on NM_000079.4) | Nonsense Mutation (SNP) | VAF 5/72 reads (7%) | catalogued as COSV53685526; called by muse, mutect2
- CLIC1 | c.701A>T p.E234V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV101007445; called by muse, mutect2, varscan2
- COL1A2 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51955577, COSV51957282; called by muse, mutect2, varscan2
- COL21A1 | c.2541G>C p.L847F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV55161107, COSV55163176; called by muse, mutect2, varscan2
- COL2A1 | c.3814C>A p.P1272T | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61534860; called by muse, mutect2, varscan2
- CR2 | c.2024G>C p.G675A | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV100889675, COSV65507413; called by muse, mutect2
- CRIM1 | c.2389C>A p.P797T | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54863231; called by muse, mutect2, varscan2
- CSMD3 | c.9613A>G p.M3205V (on ENST00000297405 / NM_001363185.1; = p.M3036V on NM_052900.3) | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs762522299, COSV52331748; called by muse, mutect2
- CT55 | c.534A>T p.E178D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV52277704; called by muse, mutect2
- DACT1 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV60020571; called by muse, mutect2, varscan2
- DCLK3 | c.1028G>T p.R343L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV69363021; called by muse, mutect2, varscan2
- DLG2 | c.1801A>T p.R601W | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54640269; called by muse, mutect2, varscan2
- DMXL1 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV60710449; called by muse, mutect2
- DNAH9 | c.2439G>T p.E813D | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV52347338; called by muse, mutect2, varscan2
- DNAJC6 | c.2657A>G p.Y886C | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368437431; called by muse, mutect2, varscan2
- DOK5 | c.831C>A p.S277R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV52819675, COSV99373540; called by muse, mutect2, varscan2
- DRC7 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as COSV61054366; called by muse, mutect2, varscan2
- EFCAB5 | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV57929284; called by muse, mutect2, varscan2
- EGFR | c.630G>T p.L210= | Splice Region (SNP) | VAF 34/346 reads (10%) | catalogued as COSV51795975; called by muse, mutect2
- EHHADH | c.2012G>T p.G671V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51629867; called by muse, mutect2, varscan2
- ELMO2 | c.1182G>T p.E394D | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51682685; called by muse, mutect2, varscan2
- EML5 | c.2540G>T p.G847V | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61345116; called by muse, mutect2, varscan2
- EPHA6 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV67570518, COSV67579536; called by muse, mutect2, varscan2
- EPPK1 | c.3952G>T p.G1318W | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV73261122; called by muse, mutect2, varscan2
- EPS15L1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV50168449; called by muse, mutect2
- FAM120A | c.2246A>T p.Y749F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV52904472; called by muse, mutect2, varscan2
- FBF1 | c.850G>A p.E284K (on ENST00000586717; = p.E298K on NM_001319193.1) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs199958081, COSV100044845; called by muse, varscan2
- FBXL5 | c.1440G>T p.W480C | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs149921734, COSV58009934; called by muse, mutect2, varscan2
- FBXL5 | c.1319C>G p.S440C | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.533); catalogued as COSV58010692; called by muse, mutect2, varscan2
- FER1L6 | c.2095C>G p.Q699E | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV67549660; called by muse, mutect2, varscan2
- FER1L6 | c.4953del p.N1652Tfs*30 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as COSV67548284; called by mutect2, pindel, varscan2
- FGF18 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 11/118 reads (9%) | catalogued as COSV51126126; called by muse, mutect2
- FHOD3 | c.1097C>A p.S366* | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | catalogued as COSV57163666, COSV57172137; called by muse, mutect2, varscan2
- FIG4 | c.239A>T p.Q80L | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as COSV57787236; called by muse, mutect2, varscan2
- FLG2 | c.4873G>C p.G1625R | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV66168366; called by muse, mutect2
- GABRB1 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752134548, COSV99780572; called by muse, mutect2, varscan2
- GABRR1 | c.727A>G p.I243V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as COSV65619322; called by muse, mutect2
- GALNT2 | c.1190A>T p.Y397F | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV64194557; called by muse, mutect2
- GBP4 | c.916+1G>T p.X306_splice | Splice Site (SNP) | VAF 11/76 reads (14%) | catalogued as COSV63254045; called by muse, mutect2, varscan2
- GCNT1 | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV65057474; called by muse, varscan2
- GEMIN5 | c.3970G>A p.E1324K | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV53560230; called by muse, mutect2
- GGH | c.875A>T p.E292V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52650221; called by muse, mutect2
- GIMAP5 | c.103A>C p.K35Q | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57529946; called by muse, mutect2, varscan2
- GNB1L | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.038); catalogued as COSV61547906, COSV61550112; called by muse, mutect2, varscan2
- GPC5 | c.1576A>T p.M526L | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65595290; called by muse, mutect2
- GPR22 | c.98C>A p.P33Q | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV51749693; called by muse, mutect2, varscan2
- GPR85 | c.581T>A p.I194N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV51783374; called by muse, mutect2, varscan2
- GRIA4 | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56890545; called by muse, mutect2, varscan2
- GTPBP10 | c.316A>T p.I106L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.02); catalogued as COSV55987363; called by muse, mutect2, varscan2
- H2BU1 | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as COSV64209567, COSV64209713; called by muse, mutect2, varscan2
- HAVCR2 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs762519713, COSV57152441, COSV57154943; called by muse, mutect2
- HBE1 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 21/95 reads (22%) | catalogued as COSV53079958; called by muse, mutect2, varscan2
- HDAC9 | c.12G>T p.M4I | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV101286709, COSV67784943; called by muse, mutect2, varscan2
- HTR7 | c.1019G>T p.W340L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99519173; called by muse, mutect2, varscan2
- IL1A | c.623C>G p.P208R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54519497; called by muse, mutect2, varscan2
- INCENP | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV53915264; called by muse, mutect2, varscan2
- KCNB1 | c.1410G>T p.E470D | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as COSV65568002; called by muse, mutect2, varscan2
- KCNH8 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.544); catalogued as COSV60462551; called by muse, mutect2, varscan2
- KCNT1 | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.917); catalogued as COSV53684255; called by muse, mutect2, varscan2
- KDR | c.3496G>C p.A1166P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55764093; called by muse, mutect2, varscan2
- KRTAP5-1 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.367); catalogued as COSV66298960; called by muse, mutect2
- LAMA1 | c.1262-1G>T p.X421_splice | Splice Site (SNP) | VAF 8/51 reads (16%) | catalogued as COSV67544966; called by muse, mutect2, varscan2
- LAMA1 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV67536268; called by muse, mutect2, varscan2
- LILRB2 | c.1488G>C p.Q496H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV58743588, COSV58744966; called by muse, mutect2
- LNPK | c.1225G>C p.V409L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV55823519; called by muse, mutect2, varscan2
- LRFN5 | c.2128G>T p.V710F | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV53254377; called by muse, mutect2, varscan2
- LRRIQ1 | c.2473C>T p.L825F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67829985; called by muse, mutect2, varscan2
- MAGEC3 | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.679); catalogued as COSV53579546; called by muse, varscan2
- MAGEC3 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV53579553; called by muse, varscan2
- MECR | c.231G>T p.M77I | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as COSV55285206; called by muse, mutect2, varscan2
- MED23 | c.1325A>C p.K442T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as COSV63432270; called by muse, mutect2, varscan2
- MGAM | c.1123T>A p.Y375N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72074545; called by muse, mutect2, varscan2
- MUC17 | c.5690C>T p.P1897L | Missense Mutation (SNP) | VAF 75/306 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.694); catalogued as COSV60287257; called by muse, mutect2, varscan2
- MYLK2 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.186); catalogued as COSV65658982; called by muse, mutect2, varscan2
- NAALAD2 | c.557G>C p.C186S | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV58960595; called by muse, mutect2, varscan2
- NELL1 | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54260371; called by muse, mutect2, varscan2
- NFKBID | c.145G>C p.G49R (on ENST00000396901; = p.G201R on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61728443; called by muse, mutect2, varscan2
- NKD2 | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV99723876; called by muse, mutect2, varscan2
- NOS2 | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV58227773; called by muse, mutect2
- NPAP1 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV61511820; called by muse, mutect2
- OR10A6 | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100564250; called by mutect2, varscan2
- OR13C4 | c.907G>T p.V303L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV52926469; called by muse, mutect2, varscan2
- OR2L8 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV61726598; called by muse, mutect2
- OR2T1 | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63541797; called by muse, mutect2
- OR2V2 | c.425G>C p.C142S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV60315494; called by muse, mutect2
- OR4C15 | c.736C>A p.H246N (on ENST00000314644; = p.H192N on NM_001001920.2) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as COSV58951043, COSV58956031; called by muse, mutect2, varscan2
- OR4C16 | c.347del p.T116Rfs*16 | Frame Shift Del (DEL) | VAF 19/134 reads (14%) | catalogued as COSV58942583; called by mutect2, pindel*, varscan2
- OR4D10 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770395543, COSV73260019; called by muse, mutect2, varscan2
- OR51S1 | c.221T>C p.L74P | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59058234; called by muse, mutect2, varscan2
- OR52N1 | c.112A>T p.S38C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV57693276; called by muse, varscan2
- OR52N5 | c.239T>A p.L80H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV57698788; called by muse, mutect2, varscan2
- ORM1 | c.305A>T p.E102V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV52279276, COSV52279592; called by muse, mutect2, varscan2
- OVCH1 | c.3140C>A p.P1047Q | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.81); catalogued as rs1457531219, COSV58962263; called by muse, varscan2
- PATJ | c.2494G>T p.D832Y | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV57160996; called by muse, mutect2, varscan2
- PCDH10 | c.2104C>A p.P702T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV52104765; called by mutect2, varscan2
- PCDH12 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774340238, COSV51521121; called by muse, mutect2, varscan2
- PCDHB14 | c.901G>T p.V301F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); catalogued as rs781955583, COSV53388104; called by muse, mutect2, varscan2
- PCDHB6 | c.1196A>T p.Y399F | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV50695541; called by muse, mutect2
- PDE6C | c.1406C>A p.S469Y | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV65115050; called by muse, mutect2, varscan2
- PDGFRA | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.624); catalogued as COSV57267589; called by muse, mutect2, varscan2
- PHYHIPL | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV65848555; called by muse, mutect2, varscan2
- PLAG1 | c.1292C>A p.P431H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.308); catalogued as COSV57610908, COSV57613123; called by muse, mutect2
- PLCG2 | c.3353A>T p.E1118V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100842110; called by muse, mutect2, varscan2
- PLEKHG3 | c.34A>G p.S12G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as COSV55979693; called by muse, mutect2
- PNN | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as rs773801437, COSV53766168; called by muse, mutect2, varscan2
- POC1A | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56591277; called by muse, mutect2, varscan2
- POF1B | c.1629G>T p.R543S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.985); catalogued as COSV53133586; called by muse, mutect2
- POM121L12 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV68692849; called by muse, mutect2, varscan2
- PPARGC1A | c.1324A>T p.K442* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV53527125; called by muse, mutect2, varscan2
- PRICKLE4 | c.277C>A p.P93T (on ENST00000359201; = p.P133T on NM_013397.6) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV100138704; called by muse, mutect2
- PRORP | c.678G>T p.W226C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51617715, COSV51622397; called by muse, mutect2, varscan2
- PRSS1 | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61192641; called by muse, varscan2
- PRTG | c.1174A>G p.I392V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as rs376900886; called by muse, mutect2, varscan2
- PSG11 | c.362C>A p.T121N | Missense Mutation (SNP) | VAF 102/224 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1250117363, COSV60454991; called by muse, mutect2, varscan2
- PTPRK | c.4210G>C p.V1404L (on ENST00000368215 / NM_001291984.2; = p.V1405L on NM_002844.4) | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV63896468; called by muse, mutect2, varscan2
- PTPRN2 | c.1402G>C p.A468P | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs151334443, COSV67035394; called by muse, mutect2, varscan2
- PXDNL | c.3340C>T p.P1114S | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as rs1286186038, COSV62486493; called by muse, mutect2, varscan2
- RALGAPA2 | c.5563G>T p.D1855Y | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV52496079; called by muse, mutect2, varscan2
- RBBP8 | c.1471C>G p.L491V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs561139689, COSV59092266; called by muse, mutect2, varscan2
- RBM15B | c.1163A>T p.D388V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60371819; called by muse, mutect2, varscan2
- RHOT2 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as rs897387617, COSV54808265; called by muse, mutect2, varscan2
- RIMS2 | c.3682G>T p.D1228Y | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51677027, COSV99160151; called by muse, mutect2, varscan2
- RIMS2 | c.4665G>T p.W1555C (on ENST00000666250 / NM_001348490.2; = p.W1126C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51677034, COSV51681526; called by muse, mutect2, varscan2
- RIMS4 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV65719131, COSV65719628; called by muse, mutect2, varscan2
- RNF20 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV66660967; called by muse, mutect2, varscan2
- RREB1 | c.1966G>C p.G656R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV58557102; called by muse, mutect2, varscan2
- RTL4 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV61206325; called by muse, mutect2, varscan2
- RTN3 | c.2521G>C p.D841H (on ENST00000377819 / NM_001265589.2; = p.D822H on NM_201428.3) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV58028396; called by muse, mutect2, varscan2
- RTP5 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.062); catalogued as COSV100574707, COSV58319884; called by muse, mutect2, varscan2
- SATB2 | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as COSV53493240; called by muse, mutect2, varscan2
- SDK2 | c.3467T>C p.V1156A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV66185303; called by muse, mutect2, varscan2
- SEPTIN7 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV63254816; called by muse, mutect2, varscan2
- SERPINA3 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV67586025; called by muse, mutect2, varscan2
- SH3BP4 | c.1867A>T p.R623W | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60643739; called by muse, mutect2, varscan2
- SIPA1L1 | c.4512-2A>C p.X1504_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | catalogued as COSV62169870; called by muse, mutect2
- SLC12A6 | c.2969G>A p.R990H (on ENST00000354181 / NM_001365088.1; = p.R939H on NM_005135.2) | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs868273832, COSV51625658; called by muse, mutect2
- SLC22A1 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61452220; called by muse, mutect2, varscan2
- SLC25A12 | c.311G>C p.G104A | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as COSV55533129; called by muse, mutect2
- SLC35F1 | c.543C>A p.Y181* | Nonsense Mutation (SNP) | VAF 83/286 reads (29%) | catalogued as COSV64502577, COSV64511796; called by muse, mutect2, varscan2
- SLC4A3 | c.2732G>C p.R911P | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56093346, COSV56096053; called by muse, mutect2
- SLITRK2 | c.2043C>A p.D681E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59425016; called by muse, mutect2, varscan2
- SMC4 | c.1694T>A p.L565H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61004565; called by muse, mutect2, varscan2
- SNAI2 | c.626-2A>T p.X209_splice | Splice Site (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99194953; called by muse, mutect2
- SNTG1 | c.1038+1del | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | catalogued as COSV99384448; called by mutect2, pindel, varscan2
- SPP2 | c.380T>G p.V127G | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV51446829; called by muse, mutect2, varscan2
- ST8SIA1 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as COSV53953557; called by muse, mutect2, varscan2
- STAB1 | c.1835G>T p.R612L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100401793, COSV58738453; called by muse, mutect2
- STAB2 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); catalogued as COSV66338394; called by muse, mutect2, varscan2
- STAM2 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55729697; called by muse, mutect2, varscan2
- STUM | c.261G>T p.R87S | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV64684126; called by muse, mutect2, varscan2
- STX2 | c.50G>C p.G17A | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.194); catalogued as COSV55433244; called by muse, mutect2, varscan2
- SYCE2 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 21/89 reads (24%) | catalogued as COSV53366477; called by muse, mutect2, varscan2
- TAC4 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.568); catalogued as COSV58004753; called by muse, mutect2, varscan2
- TAF4B | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV52303347; called by muse, mutect2
- TBX22 | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1367758632, COSV64787641; called by muse, mutect2, varscan2
- TEX15 | c.4024G>T p.V1342L (on ENST00000256246; = p.V1725L on NM_001350162.2) | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as COSV56345596; called by muse, mutect2, varscan2
- TGM4 | c.1481T>G p.L494R | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV56093724; called by muse, mutect2, varscan2
- TMEM74 | c.151A>G p.R51G | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as rs1186978087, COSV52463106; called by muse, mutect2
- TOGARAM2 | c.1798G>T p.V600L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV65421255; called by muse, mutect2
- TRIM56 | c.1322A>T p.Q441L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); catalogued as COSV100047075; called by muse, mutect2, varscan2
- TRPS1 | c.49G>C p.E17Q (on ENST00000220888 / NM_001330599.2; = p.E30Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV55228483, COSV55238235; called by muse, mutect2, varscan2
- TSHZ2 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV61587607; called by muse, mutect2, varscan2
- TTPA | c.231A>T p.R77S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52646522; called by mutect2, varscan2
- TULP2 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as rs1329288025, COSV54386069; called by muse, mutect2
- UBR5 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.899); catalogued as COSV55285653; called by muse, mutect2, varscan2
- VPS13C | c.1351G>T p.E451* (on ENST00000644861 / NM_020821.3; = p.E408* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV51426997; called by muse, mutect2, varscan2
- YPEL3 | c.125A>G p.Q42R (on ENST00000398838 / NM_001145524.2; = p.Q80R on NM_031477.5) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.9); catalogued as COSV54221817; called by muse, mutect2, varscan2
- ZIM2 | c.1298C>G p.A433G | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as COSV55632106, COSV55632367; called by muse, mutect2, varscan2
- ZMIZ2 | c.1559G>T p.R520L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54807652; called by muse, mutect2, varscan2
- ZNF107 | c.737G>T p.C246F | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61332479; called by muse, mutect2, varscan2
- ZNF16 | c.884G>T p.C295F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52763490; called by muse, mutect2, varscan2
- ZNF256 | c.1172G>T p.S391I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.204); catalogued as COSV99990681; called by muse, mutect2, varscan2
- ZNF488 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | catalogued as rs1310640127; called by muse, mutect2, varscan2
- ZNF594 | c.1447A>G p.T483A | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV101280393; called by muse, mutect2, varscan2
- CCL3L3 | c.83C>G p.A28G | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2
- CLEC14A | c.1320del p.P441Rfs*24 | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- HSPA1B | c.*3dup | Frame Shift Ins (INS) | VAF 24/103 reads (23%) | called by mutect2, pindel, varscan2
- IGKV1-16 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- IGLV3-27 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PRAMEF14 | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.06); called by muse, mutect2
- PRDM13 | c.1260T>G p.Y420* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- PTPRC | c.1467del p.W489* | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- TRBV19 | c.334A>T p.S112C | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- TRBV3-1 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- WDFY3 | c.8554del p.Y2852Ifs*14 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.1404C>A p.P468= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV61261994; called by muse, mutect2, varscan2
- AMZ1 | c.259C>A p.R87= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV100406267, COSV56686558; called by muse, mutect2, varscan2
- BRINP1 | c.492G>C p.L164= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV56298554; called by muse, mutect2, varscan2
- C1R | c.1803G>T p.L601= (on ENST00000536053 / NM_001354346.2; = p.L587= on NM_001733.7) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV73383059; called by muse, mutect2
- CALR | c.390C>T p.I130= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV100330498; called by muse, mutect2, varscan2
- CAPNS1 | c.426C>T p.D142= | Silent (SNP) | VAF 70/158 reads (44%) | catalogued as COSV55822725; called by muse, mutect2, varscan2
- CTNND2 | c.1266C>G p.P422= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV58885324; called by muse, mutect2, varscan2
- CYP4A11 | c.1455C>G p.T485= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as rs1473493860, COSV60223309; called by muse, mutect2, varscan2
- DGKQ | c.1800C>G p.L600= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs1254567264, COSV53278572; called by muse, mutect2, varscan2
- DHX33 | c.717C>T p.F239= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as COSV56578873; called by muse, mutect2, varscan2
- DHX57 | c.3126C>T p.D1042= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV54884823; called by muse, mutect2, varscan2
- DOCK2 | c.3339C>T p.D1113= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as rs1561883407, COSV56955974; called by muse, mutect2
- ENTPD3 | c.1500G>A p.L500= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV57194204; called by muse, mutect2, varscan2
- EPHA10 | c.504G>A p.E168= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV60403164; called by muse, mutect2, varscan2
- FAT4 | c.4768T>C p.L1590= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as rs1560757433, COSV67885496; called by muse, mutect2
- GABRB1 | c.528C>A p.T176= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99780566; called by muse, mutect2, varscan2
- GCNT1 | c.591C>G p.L197= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV65057468; called by muse, varscan2
- GOLGA3 | c.1815C>A p.T605= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV52630254; called by muse, mutect2, varscan2
- HAVCR2 | c.384C>A p.V128= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV57154953, COSV57155566; called by muse, varscan2
- HIC2 | c.1305G>T p.V435= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as COSV68042022; called by muse, mutect2
- KRTAP5-5 | c.81C>T p.G27= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV68784848; called by muse, varscan2
- MS4A3 | c.6C>T p.A2= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV53935925; called by muse, mutect2
- MYH3 | c.3426G>A p.R1142= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1247849989, COSV56864392; called by muse, mutect2, varscan2
- MYO18B | c.7536C>T p.S2512= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs1407996315, COSV59132676; called by muse, mutect2, varscan2
- NCKAP5 | c.3313T>C p.L1105= | Silent (SNP) | VAF 34/238 reads (14%) | catalogued as COSV58436402, COSV58453778; called by muse, mutect2, varscan2
- NID2 | c.1767G>T p.L589= | Silent (SNP) | VAF 24/150 reads (16%) | catalogued as COSV53495858; called by muse, mutect2, varscan2
- NKD2 | c.1056C>A p.A352= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99723879; called by muse, mutect2, varscan2
- NKD2 | c.1182G>A p.S394= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1421705805, COSV56891360; called by muse, mutect2
- NLRP4 | c.763C>A p.R255= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV56712737, COSV56721500; called by muse, mutect2, varscan2
- NRN1L | c.162C>T p.I54= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV59302635; called by muse, mutect2, varscan2
- NRXN3 | c.1302C>A p.G434= (on ENST00000335750 / NM_001330195.2; = p.G61= on NM_004796.6) | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV59710548, COSV59743312; called by muse, mutect2, varscan2
- NUDT7 | c.393C>T p.N131= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99215967; called by muse, mutect2, varscan2
- OR11A1 | c.447C>A p.T149= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV65820905; called by muse, mutect2, varscan2
- OR2G6 | c.273C>A p.T91= | Silent (SNP) | VAF 24/142 reads (17%) | catalogued as COSV100598052, COSV58575338; called by muse, mutect2, varscan2
- OR2M2 | c.93C>A p.V31= | Silent (SNP) | VAF 59/208 reads (28%) | catalogued as COSV62897748, COSV62898239; called by muse, mutect2, varscan2
- OR51S1 | c.81C>A p.G27= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV59058250; called by muse, mutect2, varscan2
- OR5T3 | c.585T>A p.P195= | Silent (SNP) | VAF 29/232 reads (13%) | catalogued as COSV57380389; called by muse, mutect2, varscan2
- PAPPA2 | c.1716C>A p.V572= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100866860, COSV62777448; called by muse, mutect2, varscan2
- PPFIA4 | c.1887C>A p.T629= (on ENST00000447715; = p.T630= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV55322171; called by muse, mutect2, varscan2
- PRAMEF14 | c.132C>T p.F44= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- PRR23B | c.384G>T p.L128= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100272199; called by muse, mutect2, varscan2
- PSG9 | c.1146C>A p.P382= | Silent (SNP) | VAF 68/170 reads (40%) | catalogued as COSV52484787, COSV99392220; called by muse, mutect2, varscan2
- SERGEF | c.210C>T p.L70= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as rs748353093, COSV56383089; called by muse, mutect2, varscan2
- SESTD1 | c.516A>G p.S172= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1384498727, COSV58931078; called by muse, mutect2, varscan2
- SPRED2 | c.960G>A p.E320= | Silent (SNP) | VAF 34/157 reads (22%) | catalogued as rs1387447866, COSV62692685; called by muse, mutect2, varscan2
- TDP1 | c.675G>T p.L225= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV59643092; called by muse, mutect2
- TECRL | c.432C>A p.T144= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV67086832, COSV67090948; called by muse, mutect2, varscan2
- TFAP2D | c.363G>T p.A121= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as rs1359834659, COSV50408145, COSV50414800; called by muse, mutect2, varscan2
- TMPRSS11D | c.570C>A p.G190= | Silent (SNP) | VAF 20/147 reads (14%) | catalogued as COSV52222980; called by muse, mutect2, varscan2
- URB2 | c.3498A>C p.P1166= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV50987290; called by muse, mutect2, varscan2
- VPS36 | c.324C>G p.L108= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV65199059; called by muse, mutect2, varscan2
- ZNF595 | c.1626C>A p.G542= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV59554234; called by muse, mutect2
- ZNF709 | c.1584G>T p.G528= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as COSV67194188, COSV67194655; called by muse, mutect2, varscan2
- ABL2 | c.158-9668G>T | Intron (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100772554; called by muse, mutect2
- AC024940.1 | n.2261C>A | RNA (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- ARNT2 | c.*3517C>A | 3'UTR (SNP) | VAF 26/110 reads (24%) | catalogued as COSV100308703; called by muse, mutect2, varscan2
- BCL2L14 | c.679-102C>T | Intron (SNP) | VAF 10/44 reads (23%) | catalogued as rs749896783, COSV53784079; called by muse, mutect2, varscan2
- LINC02843 | n.419T>C | RNA (SNP) | VAF 12/50 reads (24%) | catalogued as rs376284170; called by muse, mutect2, varscan2
- MGAM | c.4618+10745C>A | Intron (SNP) | VAF 10/85 reads (12%) | catalogued as COSV101527411; called by muse, mutect2, varscan2
- RSPH14 | c.*2C>T | 3'UTR (SNP) | VAF 22/102 reads (22%) | catalogued as COSV99320523; called by muse, mutect2, varscan2
- SSPOP | n.15269G>T | RNA (SNP) | VAF 4/44 reads (9%) | catalogued as COSV65129521, COSV65135239; called by muse, mutect2
